Somatic mutation profile of tumor specimen 0DLRHV from CCDI case PBBZNE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.4 years (1,237 days).
Specimen 0DLRHV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e19c1e1d-d173-46c4-b9a5-1033d28c8a4b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLRHL (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c4310438-3db0-4a56-ad28-07314bce0bb2

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.1510A>G p.M504V | Missense Mutation (SNP) | VAF 60/1363 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs397507547, CM013423, COSV61012722; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- BRAF | c.1980G>A p.M660I (on ENST00000288602 / NM_001374244.1; = p.M620I on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 112/883 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV56214981; called by muse, mutect2, varscan2
- CCN5 | c.192C>T p.C64= | Silent (SNP) | VAF 79/471 reads (17%) | catalogued as rs148940853; called by muse, mutect2, varscan2
